Somatic mutation profile of tumor specimen TCGA-ET-A2MY-01A (aliquot TCGA-ET-A2MY-01A-11D-A18F-08) from TCGA case TCGA-ET-A2MY, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 72.3 years (26,406 days).
Specimen TCGA-ET-A2MY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c4ccb21-39e7-4057-aa06-39b886b9a1d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A2MY-11B (Solid Tissue Normal), aliquot TCGA-ET-A2MY-11B-11D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ec53fec-92d6-4af7-8aba-3c17ff8f9589

The open-access MAF lists 50 somatic variants for this specimen: 39 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, mutect2, varscan2
- ABL2 | c.3239C>G p.S1080* (on ENST00000502732 / NM_007314.4; = p.S1065* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100773034, COSV61014009; called by muse, mutect2, varscan2
- ABL2 | c.3133C>T p.Q1045* (on ENST00000502732 / NM_007314.4; = p.Q1030* on NM_005158.5) | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV61014032; called by muse, mutect2
- ACBD5 | c.323T>C p.M108T (on ENST00000375888 / NM_001352568.1; = p.M110T on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65517889; called by muse, mutect2
- ADGRG5 | c.894C>G p.F298L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV61083288; called by muse, mutect2, varscan2
- CAND1 | c.1774T>A p.C592S | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV73389612; called by muse, mutect2
- CNR2 | c.150G>C p.E50D | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100991553, COSV65692917; called by muse, mutect2, varscan2
- DNAAF4 | c.930C>G p.I310M | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1228023741, COSV58248882; called by muse, mutect2, varscan2
- DOCK11 | c.6191G>A p.G2064D | Missense Mutation (SNP) | VAF 80/177 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.039); catalogued as rs376064945, COSV52238788; called by muse, mutect2, varscan2
- DTNB | c.997A>G p.I333V | Missense Mutation (SNP) | VAF 74/134 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs369472992; called by muse, mutect2, varscan2
- EVPL | c.3381C>G p.I1127M | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1363952686, COSV56910844; called by muse, mutect2, varscan2
- EXOSC3 | c.387C>G p.F129L | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV59203744; called by muse, mutect2, varscan2
- FAIM2 | c.917T>C p.F306S | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1391660428, COSV57739124; called by muse, mutect2, varscan2
- FCF1 | c.361C>G p.L121V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV62044126; called by muse, mutect2, varscan2
- GIMAP5 | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57529987, COSV57530647; called by muse, mutect2, varscan2
- GRIK1 | c.1520A>C p.Q507P | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV58717915; called by muse, mutect2, varscan2
- GRIN2B | c.1158G>A p.M386I | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as rs767555882, COSV74205882; called by muse, mutect2, varscan2
- GRINA | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV57592670; called by muse, mutect2, varscan2
- IFNGR1 | c.994C>A p.P332T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.294); catalogued as COSV62991970; called by muse, mutect2, varscan2
- INTS9 | c.1303C>G p.P435A | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV68434101; called by muse, mutect2, varscan2
- JUN | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs749502446, COSV64664480, COSV64664625; called by muse, mutect2, varscan2
- KRTAP10-5 | c.488G>C p.C163S | Missense Mutation (SNP) | VAF 29/201 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as COSV59961735; called by muse, mutect2, varscan2
- LZTR1 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53145725, COSV99302293; called by muse, mutect2, varscan2
- NCKIPSD | c.1893C>G p.F631L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV53660847; called by muse, mutect2, varscan2
- NISCH | c.4249G>A p.D1417N | Missense Mutation (SNP) | VAF 29/152 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV58736039; called by muse, varscan2
- PIP4K2C | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV61606135; called by muse, mutect2, varscan2
- PNOC | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.435); catalogued as rs533728896, COSV57283547; called by mutect2, varscan2
- PPAN-P2RY11 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV53452789; called by muse, mutect2
- PPIG | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV53643086; called by muse, mutect2, varscan2
- PRC1 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); catalogued as COSV62695256; called by muse, mutect2, varscan2
- RBPJ | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.974); catalogued as COSV60751309; called by muse, mutect2
- SACS | c.8471C>T p.S2824L | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.066); catalogued as COSV101207384, COSV66539762; called by muse, mutect2, varscan2
- SEMA3A | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54870214; called by muse, mutect2, varscan2
- TMEM26 | c.526C>G p.Q176E | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.028); catalogued as COSV53261543; called by muse, mutect2, varscan2
- UGGT2 | c.2358G>C p.E786D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV65074689; called by muse, mutect2
- VEZT | c.548G>C p.R183T | Missense Mutation (SNP) | VAF 38/271 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV54139136; called by muse, mutect2, varscan2
- ZNF250 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs2953878, COSV52969196; called by muse, mutect2, varscan2
- ZNF528 | c.1853C>G p.S618C | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773475109, COSV64619363; called by muse, mutect2, varscan2
- ANO1 | c.1839G>A p.L613= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as rs776353827, COSV60284327, COSV60288810; called by muse, mutect2, varscan2
- DYNC2I2 | c.936C>T p.F312= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as rs570806137, COSV100823758, COSV63987085; called by muse, mutect2, varscan2
- EHBP1L1 | c.1560G>C p.G520= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV58572967; called by muse, mutect2
- FANCC | c.483C>G p.L161= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100002328; called by muse, mutect2, varscan2
- KAT2A | c.933C>T p.Y311= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs782720496, COSV56790818; called by muse, mutect2, varscan2
- RIF1 | c.4125G>A p.E1375= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV54615204, COSV54616943; called by muse, mutect2, varscan2
- SERPINA5 | c.1173C>T p.F391= | Silent (SNP) | VAF 64/458 reads (14%) | catalogued as rs986187296, COSV61574070; called by muse, mutect2, varscan2
- SESN1 | c.237C>T p.G79= (on ENST00000356644 / NM_001199933.1; = p.G138= on NM_014454.3) | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV57420776; called by muse, mutect2
- USP45 | c.915G>C p.V305= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV59680538; called by muse, mutect2, varscan2
- ZNF786 | c.1974G>A p.V658= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV60276034; called by muse, mutect2, varscan2
- ANAPC11 | c.110-584C>T | Intron (SNP) | VAF 10/44 reads (23%) | catalogued as rs1342853463, COSV58711269; called by muse, mutect2, varscan2
